Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5872, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5872-02A (Recurrent Tumor).

[page 1 of 2]
Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: Location: Received:
Gender: F Accnt: Reported:
Physician(s):
Phy Location:

Clinical History

The patient is a -year-old woman with a past history of left frontal mixed oligoastrocytoma diagnosed on

LOH negative, treated with XRT and Temozolomide. Currently the patient experiences altered mental status, and on imaging has new abnormal signal with nodular enhancement.

Operative Diagnoses

Recurrent frontal oligoastrocytoma

Operation / Specimen

A: Brain, left frontal brain tumor, biopsy

B: Brain, left frontal brain tumor, biopsy

Pathologic Diagnosis

A. Brain, left frontal brain tumor, biopsy:

1. Necrotic tumor and brain tissue.

2. Scant viable tumor cells.

3. Radiation induced changes.

B. Brain, left frontal brain tumor, biopsy:

1. Recurrent/residual oligoastrocytoma.

2. Radiation induced changes (see comment).

Comment

Scant viable tumor is present in specimen A. and definite viable tumor is present in specimen B. Tumor cells show moderately pleomorphic round to oval to angulated nuclei. Mitotic figures are rare. Necrosis, astrogliosis, vascular changes and chronic inflammation related to radiation therapy are noted. Immunohistochemical stains are performed on specimen B. GFAP demonstrated reactive astrogliosis and highlights occasional tumor cells. The Ki-67 labeling index is approximately 2 to 3% in the tumor areas of lower cellularity and approximately 5 to 10% in areas of higher cellularity, but this higher activity is often associated with chronic inflammation and/or vascular changes. With the exception of the radiation induced changes, the remaining tumor appears histologically similar to the patient's previous specimen in terms of histopathological grade being. Some mild microvascular proliferation is noted, but is not definitely associated with tumor, as it also appears in areas of reactive gliosis, and may be secondary to radiation. Convincing histopathological evidence for definite transformation from a WHO grade II to grade III lesion is lacking. This could be due to sampling phenomenon. The fact that the lesion shows new enhancing foci radiologically however suggests that it has progressed to a WHO grade III lesion. Clinical correlation is required.

Surgical Pathology

Page 2 of 3

ICD-O-3

Oligoastrocytoma, grade II
9450/3

Site Brain, supratentorial NOS
C71.0

Path @ Brain, frontal lobe
C71.1

JW 9/20/13

BCR pathologist
confirms grade II
is appropriate at
this time

BCR

[page 2 of 2]
Electronically Signed Out

Senior Staff Pathologist
Senior Staff Pathologist

Consultant:

Intra-Operative Consultation

B.

Brain, left frontal brain tumor, biopsy: Extensive necrosis and focal atypical glial proliferation (consistent with glial neoplasm; large portions of tissue for permanents). Touch preparation smears performed at

and results reported to the Physician of Record.
Senior

Staff Pathologist

Gross Description

A.

Brain, left frontal brain tumor, biopsy:

Fixative: None

General: Received are multiple tan-yellow fragments of friable brain tissue with grey-brown areas of discoloration and necrosis, measuring 4.2 x 4 x 1.2 cm in aggregate.

A1-3: Entirely submitted

B.

Brain, left frontal brain tumor, biopsy:

Fixative: None

General: Received are multiple tan-yellow fragments of friable brain tissue with grey-brown areas of discoloration

measuring 10.3 x 5.2 x 1.1 cm in aggregate.

B1-9: Entirely submitted

Resident Pathologist

ICD-9(s): 191.9 191.9

Billing Fee Code(s): A:

B:

Histo Data

Part A: Brain, left frontal brain tumor, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

TPS H&E x 1 1

H&E x 1 2

H&E x 1 3

Part B: Brain, left frontal brain tumor, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

TPS H&E x 1 1

Surgical Pathology

Page 3 of 3

H&E x 1 2

mGFAP-DA x 1 3

H&E x 1 3

MIB1-DA x 1 3

H&E x 1 4

MIB1-DA x 1 4

H&E x 1 5

H&E x 1 6

H&E x 1 7

H&E x 1 8

H&E x 1 9

Source: NCI Genomic Data Commons file 8fd85d1c-edc2-4550-9881-ed6e00eac98b (TCGA-DU-5872.86EEC915-5F91-4C9E-B243-A26C2ACC04CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).